Surgical pathology report (de-identified scan), TCGA case TCGA-22-5482, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5482-01A (Primary Tumor).

DIAGNOSIS:

Lung, superior division of left upper lobe, resection: Grade 3 (of 4) squamous cell carcinoma forming a 4.0 x 3.2 x 2.5 cm subpleural mass. The tumor extends close to the visceral pleura. Pleural invasion will be assessed on permanent sections and will be reported in an addendum. The bronchial resection margin is negative for tumor.

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (2) subaortic (station 5) lymph nodes.
- No tumor is identified in multiple (2) para-aortic (station 6) lymph nodes.
- No tumor is identified in multiple (2) subcarinal (station 7) lymph nodes.
- No tumor is identified in a single pulmonary ligament (station 9) lymph node.

Lymph nodes, intrapulmonary/hilar, excision:

- No tumor is identified in multiple (5) intrapulmonary peribronchial lymph nodes.
- No tumor is identified in multiple (2) left hilar (station 10L) lymph nodes.
- No tumor is identified in multiple (8) interlobar (station 11) lymph nodes. The specimen labeled "station 11 lymph nodes No. 2" did not contain lymphoid tissue.

ADDENDUM:

Focal invasion into visceral pleura is present. The VVG stain supports this finding.

Source: NCI Genomic Data Commons file 1b2cbd05-e4e0-40c8-8c22-07b4841e3799 (TCGA-22-5482.B98AFF53-A7E3-4BF9-B0B3-608F20940AC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).